Gene-level copy-number profile of tumor specimen TCGA-85-A5B5-01A from TCGA case TCGA-85-A5B5, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.7 years (21,450 days).
Specimen TCGA-85-A5B5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.076f17b1-bbfd-411c-ad93-b9f96a60c9f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A5B5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3046a47e-fdd5-46a2-beca-c09879c9f052

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 181; copy number 2: 27,201; copy number 3: 11,243; copy number 4: 13,762; copy number 5: 5,861; copy number 6: 214; copy number 7: 591; copy number 8: 644; copy number 9: 9; copy number 11: 20; copy number 17: 28; copy number 18: 15; copy number 26: 38; copy number 29: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A5B5-01A-21D-A26L-01): tumor purity 0.8, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,394 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,491,636–39,672,038, 9 genes, copy number 5: BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A.
- chr2:116,687,218–133,568,463, 324 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:108,907,792–198,222,513, 1,611 genes, copy number 5–26 (within-gene range 3–26) (broad region; genes not listed).
- chr4:55,215,624–56,328,625, 25 genes, copy number 5 (within-gene range 3–5): RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161.
- chr5:33,888,056–36,242,279, 46 genes, copy number 6: RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1.
- chr6:63,193,072–63,779,336, 16 genes, copy number 5: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 5: AL354719.1, SCAT8, GCNT1P4.
- chr8:46,028,804–139,508,971, 1,326 genes, copy number 5 (broad region; genes not listed).
- chr11:68,870,664–71,252,577, 61 genes, copy number 9–29 (broad region; genes not listed).
- chr14:21,887,857–86,401,285, 1,308 genes, copy number 5–6 (broad region; genes not listed).
- chr15:19,878,555–32,745,106, 474 genes, copy number 5 (broad region; genes not listed).
- chr15:32,836,983–32,837,326, 1 gene, copy number 5: AC090877.1.
- chr17:4,959,226–5,419,676, 26 genes, copy number 6 (within-gene range 2–6): SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2, ZFP3, ZNF232, ZNF232-AS1, USP6, AC012146.3, ZNF594, AC087500.1, SCIMP, AC087500.2, RABEP1, NUP88, AC015727.1.
- chr18:64,677,796–65,920,942, 9 genes, copy number 5–7: AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1.
- chr20:25,624,045–64,313,132, 941 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:15,290,718–44,625,419, 1,214 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 181. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
